Gene-level copy-number profile of specimen HCM-CSHL-0670-C18-85M from HCMI case HCM-CSHL-0670-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: G2; Age at diagnosis: 54.2 years (19,808 days).
Specimen HCM-CSHL-0670-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 58489503-ffc9-499b-b04c-ae2462a89829.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0670-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/444d993a-4f24-4399-a220-b5aefc5ced07

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 635; copy number 2: 1,280; copy number 3: 4,968; copy number 4: 18,759; copy number 5: 18,047; copy number 6: 11,648; copy number 7: 1,138; copy number 8: 1,845; copy number 9: 66; copy number 14: 2; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 70 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,524,185, 5 genes, copy number 9: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr7:7,550,104–7,620,543, 4 genes, copy number 9: AC004982.1, AC004982.2, MIOS, AC004948.1.
- chr7:7,738,524–7,742,574, 1 gene, copy number 9 (within-gene range 8–9): AC007161.1.
- chr7:12,469,621–12,542,222, 1 gene, copy number 9 (within-gene range 8–9): AC013470.2.
- chr7:12,506,007–12,571,392, 2 genes, copy number 9 (within-gene range 8–9): AC013470.1, AC005281.1.
- chr7:12,876,684–12,876,946, 1 gene, copy number 9: RN7SKP228.
- chr7:16,970,320–17,299,368, 2 genes, copy number 9 (within-gene range 8–9): AC073332.1, BRWD1P3.
- chr7:19,695,461–19,709,037, 2 genes, copy number 9: POLR1F, MIR3146.
- chr7:20,217,577–20,415,754, 5 genes, copy number 9: AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1.
- chr7:26,152,198–26,213,607, 3 genes, copy number 9: NFE2L3, HNRNPA2B1, CBX3.
- chr7:27,106,184–27,462,969, 40 genes, copy number 9: HOXA3, HOXA-AS2, HOXA4, AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7, AC004080.4, HOXA9, AC004080.3, HOXA10-AS, MIR196B, HOXA10, HOXA11, HOXA11-AS, AC004080.7, AC004080.14, AC004080.8, AC004080.2, AC004080.12, AC004080.15, AC004080.13, HOXA13, HOTTIP, AC004080.9, AC004080.16, AC004080.10, AC004080.11, AC004080.1, EVX1-AS, EVX1, RPL35P4, HNRNPA1P73, AC004009.1, AC004009.3, AC004009.2, EIF4HP1, PSMC1P2.
- chr9:64,637,845–64,709,311, 2 genes, copy number 14: AL445665.1, BMS1P11.
- chr9:65,219,987–65,230,861, 2 genes, copy number 16: AL512605.1, AL512605.2.

Autosomal genes at a single copy (total copy number 1): 635. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
